Somatic mutation profile of cancer-model specimen HCM-BROD-0100-C15-85A (3D Organoid, passage 8; aliquot HCM-BROD-0100-C15-85A-01D-A786-36), derived from the primary tumor of HCMI case HCM-BROD-0100-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 64.4 years (23,514 days).
Specimen HCM-BROD-0100-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 024cf5b8-9d2a-4dd6-9e4d-9dd50b599432.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0100-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0100-C15-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa42c5d6-4a75-43a1-b883-c698ece65ff1

The open-access MAF lists 253 somatic variants for this specimen: 162 protein-altering or splice-affecting, 59 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 59, Intron 10, Nonsense Mutation 10, 5'UTR 8, RNA 7, Splice Site 6, Frame Shift Ins 4, 5'Flank 4, Splice Region 3, Frame Shift Del 3, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.658T>A p.Y220N | Missense Mutation (SNP) | VAF 233/234 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs530941076, COSV52691656, COSV52700454, COSV52760651, COSV53630086; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1229G>C p.G410A (on ENST00000373993 / NM_138932.2; = p.G402A on NM_014576.4) | Missense Mutation (SNP) | VAF 81/470 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV50983741, COSV50992038; called by muse, mutect2, varscan2
- AC004593.2 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); catalogued as rs528035980; called by muse, varscan2
- AGAP6 | c.1480C>T p.R494* (on ENST00000374056 / NM_001365867.1; = p.R517* on NM_001077665.2) | Nonsense Mutation (SNP) | VAF 278/991 reads (28%) | catalogued as rs782767193, COSV65017686; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3046C>G p.Q1016E | Missense Mutation (SNP) | VAF 88/89 reads (99%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV51845014; called by muse, mutect2, varscan2
- ANKRD9 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751023237, COSV54601208; called by muse, mutect2, varscan2
- APOBEC1 | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99981037; called by muse, mutect2, varscan2
- ARMC5 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); catalogued as rs763409959, COSV51655724; called by muse, mutect2, varscan2
- ASB18 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 245/245 reads (100%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs571890106; called by muse, mutect2, varscan2
- ATF2 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 227/365 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99908360; called by muse, mutect2, varscan2
- BRD4 | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV54590128; called by muse, mutect2, varscan2
- C4orf54 | c.4618C>T p.R1540W | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1172885644; called by muse, mutect2, varscan2
- CACNA1B | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 135/405 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs944817426; called by muse, mutect2, varscan2
- CACNA1E | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 105/368 reads (29%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as COSV62389487; called by muse, mutect2, varscan2
- CACNB2 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 118/399 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.026); catalogued as rs750972281; called by muse, mutect2, varscan2
- CATSPERE | c.2843G>A p.R948H | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs148921121; called by muse, mutect2, varscan2
- CHRD | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 85/353 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs761543822, COSV52607618; called by muse, mutect2, varscan2
- CIITA | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 225/454 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs912486797, COSV100161987, COSV60855449; called by muse, mutect2, varscan2
- CSMD1 | c.9496C>T p.R3166* (on ENST00000520002; = p.R3165* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 117/120 reads (98%) | catalogued as COSV59293387, COSV59386731; called by muse, mutect2, varscan2
- CYP4F8 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 50/50 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1190402029, COSV100358121, COSV100358167; called by muse, mutect2, varscan2
- DPP4 | c.2179G>A p.G727R | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); catalogued as rs200455229; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 139/372 reads (37%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- ERI1 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs754879094; called by muse, mutect2, varscan2
- EVC2 | c.3639G>A p.W1213* | Nonsense Mutation (SNP) | VAF 192/383 reads (50%) | catalogued as COSV100187038, COSV60399299; called by muse, mutect2, varscan2
- FAM71A | c.327dup p.R110Tfs*26 | Frame Shift Ins (INS) | VAF 60/250 reads (24%) | catalogued as rs749381759; called by mutect2, varscan2
- G3BP2 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.607); catalogued as rs1439916523, COSV62975976; called by muse, mutect2, varscan2
- GP9 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 382/618 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as rs772819137, COSV56623758; called by muse, mutect2, varscan2
- GUCY1A2 | c.691C>A p.P231T | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV56484063, COSV99977339; called by muse, mutect2, varscan2
- HCN1 | c.1654A>G p.S552G | Missense Mutation (SNP) | VAF 66/444 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs767873173; called by muse, mutect2, varscan2
- ICE1 | c.1648A>C p.T550P | Missense Mutation (SNP) | VAF 307/378 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV56818771, COSV56834087; called by muse, mutect2, varscan2
- IL6 | c.166_169del p.Q56Ffs*11 | Frame Shift Del (DEL) | VAF 44/206 reads (21%) | catalogued as rs1208789133; called by pindel, varscan2
- IRF2BPL | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as rs1203572101; called by muse, mutect2, varscan2
- JRKL | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 312/312 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs750771684; called by muse, mutect2, varscan2
- KIRREL3 | c.1296C>A p.H432Q | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV69383612; called by muse, mutect2, varscan2
- LRFN2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.121); catalogued as rs759803528, COSV57823733; called by muse, mutect2, varscan2
- MORF4L1 | c.280G>A p.E94K (on ENST00000331268 / NM_206839.2; = p.E55K on NM_006791.4) | Missense Mutation (SNP) | VAF 65/119 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58705384; called by muse, mutect2, varscan2
- MUSK | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.963); catalogued as COSV51883929; called by muse, mutect2, varscan2
- NCKAP5 | c.3373G>A p.A1125T | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs371372513, COSV58450719; called by muse, mutect2, varscan2
- NFASC | c.317G>T p.G106V (on ENST00000339876 / NM_001378329.1; = p.G100V on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV58369867; called by muse, mutect2, varscan2
- NOVA2 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 113/361 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54359787; called by muse, varscan2
- NPAP1 | c.1356G>C p.E452D | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV61505413, COSV61510892; called by muse, mutect2, varscan2
- OLFM1 | c.703G>A p.D235N (on ENST00000371793 / NM_001282611.2; = p.D217N on NM_014279.5) | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.329); catalogued as COSV53283115; called by muse, mutect2, varscan2
- OR5M3 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV56565588; called by muse, mutect2, varscan2
- PEG10 | c.490C>T p.R164* (on ENST00000482108 / NM_001040152.2; = p.R198* on NM_015068.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 194/195 reads (99%) | catalogued as COSV101509909; called by muse, mutect2, varscan2
- PIAS3 | c.1756C>G p.P586A | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.264); catalogued as rs782337294; called by muse, mutect2, varscan2
- PRKCH | c.366G>T p.V122= | Splice Region (SNP) | VAF 49/196 reads (25%) | catalogued as COSV60651054; called by muse, mutect2, varscan2
- PTPRR | c.1498-1G>C p.X500_splice | Splice Site (SNP) | VAF 10/166 reads (6%) | catalogued as COSV99318610; called by muse, mutect2
- PTPRS | c.3665C>T p.P1222L | Missense Mutation (SNP) | VAF 105/204 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768612717; called by muse, mutect2, varscan2
- RIOK3 | c.1483C>T p.H495Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV59775529; called by muse, varscan2
- SAMD9 | c.2965G>A p.A989T | Missense Mutation (SNP) | VAF 112/314 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1358384466, COSV66074250; called by muse, mutect2, varscan2
- SDF4 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs1557517777, COSV55420785, COSV99027809; called by muse, mutect2, varscan2
- SYT16 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 128/394 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs191032067; called by muse, mutect2, varscan2
- TAF6L | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 110/326 reads (34%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.206); catalogued as rs1319177545, COSV53668464, COSV53670261; called by muse, mutect2, varscan2
- TEX15 | c.688G>A p.E230K (on ENST00000256246; = p.E613K on NM_001350162.2) | Missense Mutation (SNP) | VAF 122/135 reads (90%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as rs555117933; called by muse, mutect2, varscan2
- TFAP2C | c.1231G>T p.A411S | Missense Mutation (SNP) | VAF 296/1001 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.07); catalogued as rs369684214; called by muse, mutect2, varscan2
- TIGD4 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364050596; called by muse, mutect2, varscan2
- TMEM200A | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 87/370 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); catalogued as rs1283078291; called by muse, mutect2, varscan2
- TMEM54 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs141498823; called by muse, mutect2, varscan2
- TOR1AIP2 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV62626471; called by muse, mutect2, varscan2
- TYR | c.642C>A p.F214L | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as CD102897; called by muse, mutect2
- VPS72 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 99/450 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.574); catalogued as rs1254239068; called by muse, mutect2, varscan2
- WDFY4 | c.8219G>A p.R2740K | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762366232; called by muse, mutect2, varscan2
- XIRP1 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 151/310 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100453920; called by muse, mutect2, varscan2
- ZNF619 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 71/129 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs377170323; called by muse, mutect2, varscan2
- ZNF735 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 28/580 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.977); catalogued as rs1428362486; called by muse, mutect2
- ZNF813 | c.162G>C p.M54I | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs1035354364; called by muse, mutect2, varscan2
- ZNF831 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV100926023, COSV64038770; called by muse, mutect2, varscan2
- ABCC6 | c.2291C>G p.A764G | Missense Mutation (SNP) | VAF 159/322 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC9 | c.2657A>T p.K886I | Missense Mutation (SNP) | VAF 181/181 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ANKRD11 | c.7700C>T p.P2567L | Missense Mutation (SNP) | VAF 157/696 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ARAP3 | c.200A>G p.E67G | Missense Mutation (SNP) | VAF 178/178 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- B3GALT6 | c.758A>G p.D253G | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- BAG6 | c.3134C>T p.S1045L (on ENST00000676571; = p.S998L on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/308 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- BAG6 | c.1939C>T p.Q647* (on ENST00000676571; = p.Q600* on NM_080702.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 126/392 reads (32%) | called by muse, mutect2, varscan2
- BICRA | c.2627C>A p.A876D | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- C17orf99 | c.200A>G p.N67S | Missense Mutation (SNP) | VAF 25/351 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.647); called by muse, mutect2
- CAMK4 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMK4 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- CD93 | c.996A>T p.Q332H | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDC6 | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 82/553 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CHD7 | c.2470G>T p.E824* | Nonsense Mutation (SNP) | VAF 67/250 reads (27%) | called by muse, mutect2, varscan2
- CKLF | c.333+1G>T p.X111_splice | Splice Site (SNP) | VAF 51/172 reads (30%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.3673G>A p.E1225K | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CTCFL | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 395/587 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CXCR3 | c.34A>C p.N12H | Missense Mutation (SNP) | VAF 77/152 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP17A1 | c.753+7G>A | Splice Region (SNP) | VAF 50/112 reads (45%) | called by muse, mutect2, varscan2
- DACH2 | c.570G>T p.L190F | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- DBNDD2 | c.619G>C p.D207H | Missense Mutation (SNP) | VAF 103/593 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- DPYSL4 | c.541-1G>T p.X181_splice | Splice Site (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- DSG2 | c.514A>T p.S172C | Missense Mutation (SNP) | VAF 90/349 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.277); called by muse, mutect2
- ELP1 | c.2737-1G>A p.X913_splice | Splice Site (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- FAT4 | c.14582A>C p.K4861T | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- FLCN | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 179/526 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXB2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRAS1 | c.11878G>A p.D3960N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- FRMD4A | c.1129T>A p.S377T | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- GML | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- GPR152 | c.1339A>T p.T447S | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.011); called by muse, mutect2
- GPR33 | c.989G>T p.R330M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, varscan2
- GSG1L2 | c.603G>T p.W201C | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTF2IRD1 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 89/595 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF3C3 | c.690A>T p.Q230H | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HIP1R | c.3052C>G p.P1018A | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- IARS2 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 195/308 reads (63%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDI1 | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KDM1A | c.1882G>C p.G628R | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1586 | c.619dup p.I207Nfs*2 | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | called by mutect2, varscan2
- LAIR2 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- LILRB2 | c.920C>G p.S307W | Missense Mutation (SNP) | VAF 100/289 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMUT | c.921C>A p.F307L | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYRIP | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAPRT | c.355-1G>C p.X119_splice | Splice Site (SNP) | VAF 37/936 reads (4%) | called by muse, mutect2
- NCOA2 | c.1749A>T p.K583N | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- NEB | c.9916T>C p.S3306P | Missense Mutation (SNP) | VAF 103/181 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- NEMP1 | c.1100A>G p.N367S (on ENST00000300128 / NM_001130963.2; = p.N294S on NM_015257.3) | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NLRP14 | c.3082T>C p.Y1028H | Missense Mutation (SNP) | VAF 145/145 reads (100%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOG | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NUTM2E | c.2323T>A p.W775R | Missense Mutation (SNP) | VAF 86/196 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by mutect2, varscan2
- OPLAH | c.1135G>T p.G379* | Nonsense Mutation (SNP) | VAF 128/959 reads (13%) | called by muse, mutect2, varscan2
- OR51S1 | c.551A>T p.H184L | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR52W1 | c.485T>A p.V162E | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.377); called by muse, mutect2
- OR5M1 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 209/211 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR9I1 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PCDHB1 | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PGAM1 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 86/177 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- PLXNA3 | c.4306C>T p.L1436F | Missense Mutation (SNP) | VAF 187/187 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PMM2 | c.607A>T p.T203S | Missense Mutation (SNP) | VAF 112/237 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2
- POTEH | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 67/630 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PPM1M | c.642G>T p.E214D (on ENST00000296487; = p.E375D on NM_144641.4) | Missense Mutation (SNP) | VAF 109/220 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- PPP1R3F | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PPP1R3F | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 176/176 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- PRMT8 | c.945del p.F315Lfs*46 | Frame Shift Del (DEL) | VAF 73/246 reads (30%) | called by mutect2, pindel, varscan2
- PRRC2A | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 223/695 reads (32%) | called by muse, mutect2, varscan2
- PRRC2A | c.4717G>A p.E1573K | Missense Mutation (SNP) | VAF 81/335 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- PTCD3 | c.309+3_309+6del p.X103_splice | Splice Site (DEL) | VAF 22/103 reads (21%) | called by mutect2, pindel, varscan2
- PTK6 | c.704A>G p.E235G | Missense Mutation (SNP) | VAF 57/399 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RADIL | c.793G>C p.V265L | Missense Mutation (SNP) | VAF 131/629 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RMC1 | c.1925dup p.K643Qfs*35 | Frame Shift Ins (INS) | VAF 28/108 reads (26%) | called by mutect2, varscan2
- SERINC3 | c.602T>G p.L201W | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- SHROOM1 | c.1886_1889dup p.V631Pfs*4 | Frame Shift Ins (INS) | VAF 39/74 reads (53%) | called by mutect2, varscan2
- SORCS3 | c.2306C>G p.A769G | Missense Mutation (SNP) | VAF 128/128 reads (100%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- SPEF2 | c.5444C>G p.S1815* | Nonsense Mutation (SNP) | VAF 14/105 reads (13%) | called by muse, mutect2, varscan2
- SPTLC2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 111/242 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- STARD9 | c.6750A>T p.K2250N | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SYNE1 | c.21076G>C p.E7026Q (on ENST00000367255 / NM_182961.4; = p.E6955Q on NM_033071.3) | Missense Mutation (SNP) | VAF 107/329 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TASOR | c.3655C>T p.Q1219* (on ENST00000355628 / NM_001365636.2; = p.Q843* on NM_015224.3) | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- TIAM1 | c.1737G>T p.K579N | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLL1 | c.2633G>C p.G878A | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM64 | c.818A>C p.N273T | Missense Mutation (SNP) | VAF 108/173 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- TNFRSF25 | c.599-3C>T | Splice Region (SNP) | VAF 157/469 reads (33%) | called by muse, mutect2, varscan2
- TNRC18 | c.5033A>T p.K1678M | Missense Mutation (SNP) | VAF 84/380 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- TTN | c.72310T>C p.W24104R (on ENST00000591111; = p.W16680R on NM_003319.4) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UGGT1 | c.4261G>A p.D1421N | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UNC79 | c.3692T>C p.V1231A (on ENST00000393151 / NM_001346218.2; = p.V1054A on NM_020818.5) | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- VOPP1 | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- WASHC5 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 95/705 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WASHC5 | c.467A>T p.K156M | Missense Mutation (SNP) | VAF 93/705 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDTC1 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WNT16 | c.409A>G p.R137G (on ENST00000222462 / NM_057168.2; = p.R127G on NM_016087.2) | Missense Mutation (SNP) | VAF 91/177 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ZFPM1 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 112/552 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ZFPM2 | c.1956G>C p.K652N | Missense Mutation (SNP) | VAF 194/968 reads (20%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF714 | c.700T>A p.C234S | Missense Mutation (SNP) | VAF 139/141 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALG8 | c.855C>T p.F285= | Silent (SNP) | VAF 605/606 reads (100%) | catalogued as rs1284684052; called by muse, mutect2, varscan2
- ANKRD11 | c.7701C>T p.P2567= | Silent (SNP) | VAF 152/688 reads (22%) | catalogued as rs1358176391, COSV56360685; called by muse, mutect2, varscan2
- APOE | c.354G>A p.A118= | Silent (SNP) | VAF 273/801 reads (34%) | called by muse, mutect2, varscan2
- BEND3 | c.391C>T p.L131= | Silent (SNP) | VAF 257/257 reads (100%) | catalogued as rs1554231931; called by muse, mutect2, varscan2
- CACNA1I | c.438C>T p.L146= | Silent (SNP) | VAF 79/127 reads (62%) | catalogued as rs1345998769; called by muse, mutect2, varscan2
- CFAP52 | c.777G>A p.L259= | Silent (SNP) | VAF 47/89 reads (53%) | called by muse, mutect2, varscan2
- COG3 | c.1359C>G p.V453= | Silent (SNP) | VAF 42/216 reads (19%) | called by muse, mutect2, varscan2
- COL27A1 | c.1533T>C p.T511= | Silent (SNP) | VAF 59/150 reads (39%) | catalogued as COSV100621048; called by muse, mutect2, varscan2
- DCAF13 | c.330C>T p.G110= | Silent (SNP) | VAF 82/248 reads (33%) | catalogued as rs776192350; called by muse, mutect2, varscan2
- DDC | c.1416C>T p.A472= | Silent (SNP) | VAF 302/632 reads (48%) | catalogued as rs892676540; called by muse, mutect2, varscan2
- DSE | c.1764T>C p.H588= | Silent (SNP) | VAF 74/229 reads (32%) | catalogued as rs1357580281; called by muse, mutect2, varscan2
- EIF4A2 | c.258A>C p.T86= | Silent (SNP) | VAF 78/226 reads (35%) | called by muse, mutect2, varscan2
- FAT3 | c.4602C>G p.L1534= | Silent (SNP) | VAF 43/150 reads (29%) | called by muse, mutect2, varscan2
- FMO2 | c.423C>T p.D141= | Silent (SNP) | VAF 114/197 reads (58%) | catalogued as rs144325714; called by muse, mutect2, varscan2
- GABRA2 | c.456G>T p.G152= | Silent (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- GABRA3 | c.888G>A p.S296= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as rs774861885, COSV64801779; called by muse, mutect2, varscan2
- GP6 | c.12C>T p.S4= | Silent (SNP) | VAF 100/333 reads (30%) | catalogued as rs1460914495; called by muse, mutect2, varscan2
- HMCN1 | c.1962T>G p.G654= | Silent (SNP) | VAF 67/193 reads (35%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.933C>T p.S311= | Silent (SNP) | VAF 47/227 reads (21%) | catalogued as rs1182159669, COSV52373428; called by muse, mutect2, varscan2
- IL9R | c.696G>A p.E232= | Silent (SNP) | VAF 189/600 reads (32%) | catalogued as rs755252410, COSV54899088; called by muse, mutect2, varscan2
- IQSEC2 | c.261C>T p.S87= | Silent (SNP) | VAF 107/107 reads (100%) | called by muse, mutect2, varscan2
- KCNN3 | c.1230C>T p.P410= | Silent (SNP) | VAF 139/484 reads (29%) | called by muse, mutect2, varscan2
- KIAA0513 | c.306C>T p.Y102= | Silent (SNP) | VAF 28/223 reads (13%) | catalogued as rs141813129; called by muse, mutect2, varscan2
- LAMA3 | c.6291G>A p.A2097= (on ENST00000313654 / NM_198129.4; = p.A488= on NM_000227.6) | Silent (SNP) | VAF 87/244 reads (36%) | catalogued as rs569425764, COSV52531966; called by muse, mutect2, varscan2
- LILRB1 | c.1575C>T p.L525= (on ENST00000427581; = p.L475= on NM_006669.6) | Silent (SNP) | VAF 83/321 reads (26%) | called by muse, mutect2, varscan2
- MYORG | c.1143C>T p.R381= | Silent (SNP) | VAF 101/436 reads (23%) | catalogued as rs1184684229, COSV52628280; called by muse, mutect2, varscan2
- NDOR1 | c.1245G>A p.R415= (on ENST00000371521 / NM_001144026.3; = p.R408= on NM_014434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 79/310 reads (25%) | called by muse, mutect2, varscan2
- NEBL | c.2916G>A p.E972= | Silent (SNP) | VAF 78/228 reads (34%) | called by muse, mutect2, varscan2
- OR5M1 | c.801T>G p.S267= | Silent (SNP) | VAF 14/219 reads (6%) | called by muse, mutect2
- ORM1 | c.138C>T p.I46= | Silent (SNP) | VAF 247/1260 reads (20%) | catalogued as rs370324189; called by muse, mutect2, varscan2
- PARD6G | c.915C>T p.G305= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as rs369128345; called by muse, mutect2, varscan2
- PCDHB11 | c.1276T>C p.L426= | Silent (SNP) | VAF 253/253 reads (100%) | catalogued as rs782595480, COSV100697139; called by muse, mutect2, varscan2
- PCDHGB2 | c.1647C>T p.R549= | Silent (SNP) | VAF 465/468 reads (99%) | catalogued as COSV53935346; called by muse, mutect2, varscan2
- PDCD2 | c.396T>A p.A132= | Silent (SNP) | VAF 144/433 reads (33%) | called by muse, mutect2, varscan2
- PHLDA3 | c.45G>A p.L15= | Silent (SNP) | VAF 163/334 reads (49%) | called by muse, mutect2, varscan2
- PNRC2 | c.192G>A p.K64= | Silent (SNP) | VAF 50/158 reads (32%) | called by muse, mutect2, varscan2
- POLR1F | c.57G>A p.L19= | Silent (SNP) | VAF 52/296 reads (18%) | catalogued as rs763005514; called by muse, mutect2, varscan2
- PRAMEF19 | c.1212G>A p.L404= | Silent (SNP) | VAF 312/1199 reads (26%) | called by muse, mutect2, varscan2
- PRX | c.2721G>A p.Q907= | Silent (SNP) | VAF 270/572 reads (47%) | called by muse, mutect2
- PTPRK | c.2913G>A p.R971= (on ENST00000368215 / NM_001291984.2; = p.R972= on NM_002844.4) | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV63902035; called by muse, mutect2, varscan2
- RIOX2 | c.165C>T p.F55= | Silent (SNP) | VAF 115/185 reads (62%) | called by muse, varscan2
- RNF114 | c.327T>G p.T109= | Silent (SNP) | VAF 86/272 reads (32%) | called by muse, mutect2, varscan2
- RTL3 | c.453A>G p.Q151= | Silent (SNP) | VAF 26/26 reads (100%) | catalogued as rs1329636864, COSV58186153; called by muse, mutect2, varscan2
- RYR3 | c.12378G>A p.A4126= (on ENST00000389232; = p.A4127= on NM_001036.6) | Silent (SNP) | VAF 108/232 reads (47%) | catalogued as rs374756167; ClinVar: likely benign; called by muse, mutect2, varscan2
- SDCCAG8 | c.198C>T p.P66= | Silent (SNP) | VAF 126/426 reads (30%) | catalogued as rs201715098, COSV100654346; called by muse, mutect2, varscan2
- SHISA5 | c.342G>C p.L114= | Silent (SNP) | VAF 62/139 reads (45%) | called by muse, mutect2, varscan2
- SLC15A2 | c.51C>T p.V17= | Silent (SNP) | VAF 70/133 reads (53%) | catalogued as rs775559415; called by muse, mutect2, varscan2
- SLC20A1 | c.291G>C p.S97= | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as rs1334546256, COSV55610331, COSV55612081; called by muse, mutect2
- SLC25A51 | c.870T>C p.Y290= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as rs1201539831; called by muse, mutect2, varscan2
- SLIT1 | c.1449G>A p.K483= | Silent (SNP) | VAF 13/188 reads (7%) | called by muse, mutect2
- SORCS1 | c.273G>T p.R91= | Silent (SNP) | VAF 136/136 reads (100%) | catalogued as COSV99545513; called by muse, mutect2, varscan2
- SYT16 | c.414T>C p.S138= | Silent (SNP) | VAF 45/185 reads (24%) | called by muse, mutect2, varscan2
- TENM2 | c.3183G>A p.E1061= (on ENST00000518659 / NM_001122679.2; = p.E829= on NM_001080428.3) | Silent (SNP) | VAF 56/116 reads (48%) | catalogued as COSV69124946; called by muse, varscan2
- TJAP1 | c.753C>T p.S251= (on ENST00000372445 / NM_001146016.1; = p.S241= on NM_080604.3) | Silent (SNP) | VAF 185/516 reads (36%) | catalogued as rs762556744; called by muse, mutect2, varscan2
- TMEM108 | c.1494C>T p.T498= | Silent (SNP) | VAF 160/238 reads (67%) | catalogued as rs1326789337, COSV58866262; called by muse, mutect2, varscan2
- TOMM70 | c.1602C>T p.I534= | Silent (SNP) | VAF 22/80 reads (28%) | called by muse, mutect2, varscan2
- TRIM46 | c.1944G>A p.S648= | Silent (SNP) | VAF 36/564 reads (6%) | catalogued as rs948466603, COSV100104228; called by muse, mutect2
- WDR59 | c.246C>T p.N82= | Silent (SNP) | VAF 158/226 reads (70%) | catalogued as rs1045744438; called by muse, mutect2, varscan2
- ZNF880 | c.867C>A p.I289= | Silent (SNP) | VAF 77/247 reads (31%) | catalogued as rs750564602; called by muse, mutect2, varscan2
- AC005863.1 | n.166G>T | RNA (SNP) | VAF 68/268 reads (25%) | called by muse, mutect2, varscan2
- AC079154.1 | n.1145A>T | RNA (SNP) | VAF 13/38 reads (34%) | called by muse, varscan2
- AC109583.1 | c.-1319+2744G>C | Intron (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- AC244394.2 | n.1260C>T | RNA (SNP) | VAF 22/570 reads (4%) | catalogued as rs781884235; called by muse, mutect2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 12/109 reads (11%) | catalogued as rs201441562; called by pindel, varscan2
- APOL2 | c.-148G>C | 5'UTR (SNP) | VAF 121/176 reads (69%) | catalogued as rs779552716; called by muse, mutect2, varscan2
- ARFGAP1 | c.*578G>A | 3'UTR (SNP) | VAF 299/1090 reads (27%) | catalogued as rs552679156; called by muse, mutect2, varscan2
- C8orf82 | c.-46A>G | 5'UTR (SNP) | VAF 72/491 reads (15%) | called by muse, mutect2, varscan2
- COL4A3 | c.-8C>T | 5'UTR (SNP) | VAF 788/789 reads (100%) | called by muse, mutect2, varscan2
- DTX3 | c.-57A>T | 5'UTR (SNP) | VAF 175/175 reads (100%) | called by muse, mutect2, varscan2
- EHMT1 | c.2505+1118C>T | Intron (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- EYS | c.749-827A>T | Intron (SNP) | VAF 74/84 reads (88%) | called by muse, mutect2, varscan2
- FEZ2 | c.904-2352C>G | Intron (SNP) | VAF 34/71 reads (48%) | called by muse, mutect2, varscan2
- FKBP6 | c.-195G>A | 5'UTR (SNP) | VAF 108/482 reads (22%) | catalogued as rs782090759; called by mutect2, varscan2
- FOLH1B | n.959A>G | RNA (SNP) | VAF 132/133 reads (99%) | called by muse, mutect2, varscan2
- G6PD | c.1458-13del | Intron (DEL) | VAF 143/359 reads (40%) | called by mutect2, pindel, varscan2
- GPR107 | chr9:130141641 C>T | 3'Flank (SNP) | VAF 77/248 reads (31%) | catalogued as rs554003487; called by muse, mutect2, varscan2
- GSDMD | chr8:143557929 C>G | 5'Flank (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- GTF2IP4 | n.1431G>T | RNA (SNP) | VAF 39/250 reads (16%) | catalogued as rs782603936; called by muse, mutect2, varscan2
- HPS3 | c.217+15G>C | Intron (SNP) | VAF 100/577 reads (17%) | called by muse, mutect2, varscan2
- IFRD2 | chr3:50292734 A>C | 5'Flank (SNP) | VAF 159/307 reads (52%) | called by muse, mutect2, varscan2
- IQCH | c.387+24933G>C | Intron (SNP) | VAF 41/100 reads (41%) | called by muse, mutect2, varscan2
- LINC02873 | n.228del | RNA (DEL) | VAF 53/258 reads (21%) | called by mutect2, pindel, varscan2
- LNPK | c.-166C>G | 5'UTR (SNP) | VAF 66/344 reads (19%) | catalogued as rs946434127; called by muse, mutect2, varscan2
- MAP2K2 | c.*14C>A | 3'UTR (SNP) | VAF 134/276 reads (49%) | catalogued as rs374728969; called by muse, mutect2, varscan2
- MIR548I1 | n.52G>A | RNA (SNP) | VAF 50/216 reads (23%) | catalogued as rs566890365; called by muse, mutect2, varscan2
- NRG1 | chr8:31640170 C>A | 5'Flank (SNP) | VAF 5/42 reads (12%) | catalogued as rs1163874603; called by muse, mutect2
- P4HTM | c.1073+37C>G | Intron (SNP) | VAF 61/142 reads (43%) | called by muse, mutect2, varscan2
- PTPRT | c.2983-729G>A | Intron (SNP) | VAF 131/318 reads (41%) | catalogued as rs778174167, COSV61974000; called by muse, mutect2, varscan2
- SCN2B | c.-28C>T | 5'UTR (SNP) | VAF 52/220 reads (24%) | catalogued as COSV54050294; called by muse, mutect2
- STX4 | chr16:31033480 G>C | 5'Flank (SNP) | VAF 75/162 reads (46%) | called by muse, mutect2, varscan2
- TRIM48 | c.-74T>G | 5'UTR (SNP) | VAF 237/237 reads (100%) | called by muse, mutect2, varscan2
